Somatic mutation profile of tumor specimen TCGA-3R-A8YX-01A (aliquot TCGA-3R-A8YX-01A-11D-A37C-09) from TCGA case TCGA-3R-A8YX, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 66.8 years (24,412 days).
Specimen TCGA-3R-A8YX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be6f6840-2a6a-4b43-a323-28fb805b0f74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3R-A8YX-10A (Blood Derived Normal), aliquot TCGA-3R-A8YX-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db39ad14-b4c7-4969-a243-4f3c142d6894

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Nonsense Mutation 4, Frame Shift Del 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP13A4 | c.3128T>G p.F1043C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.848); catalogued as COSV100710006; called by muse, mutect2, varscan2
- CARD14 | c.1489T>C p.W497R | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100712465; called by muse, mutect2
- CENPE | c.3409C>G p.Q1137E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.28); catalogued as COSV54383160, COSV99476769; called by muse, mutect2, varscan2
- COL4A4 | c.4736A>G p.H1579R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306014; called by muse, mutect2, varscan2
- CWH43 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as COSV56939695; called by muse, mutect2
- CYP3A4 | c.990A>C p.K330N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV100315371; called by muse, mutect2
- DAPK2 | c.922A>G p.K308E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV99976972; called by muse, mutect2, varscan2
- DCAF12L2 | c.278A>G p.D93G | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100758428; called by muse, mutect2, varscan2
- DLX1 | c.11C>G p.T4S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100249753; called by muse, mutect2, varscan2
- DMD | c.4376G>A p.R1459Q | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated (0.94); PolyPhen benign (0.08); catalogued as rs755835144, COSV100817315, COSV63786409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK3 | c.2678A>T p.E893V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV99808574; called by muse, mutect2, varscan2
- DOCK7 | c.2882G>C p.R961P (on ENST00000635253 / NM_001367561.1; = p.R930P on NM_033407.3) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV99222363; called by mutect2, varscan2
- DSC2 | c.1418C>A p.P473H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99199438; called by muse, mutect2, varscan2
- ELOVL7 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774514081, COSV70918909; called by muse, mutect2, varscan2
- FRS2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100165649; called by muse, mutect2, varscan2
- GBP1 | c.1591C>A p.L531M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.756); catalogued as COSV100976201; called by muse, mutect2, varscan2
- GCN1 | c.7552A>G p.T2518A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV100324524; called by mutect2, varscan2
- GLIPR1L1 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 35/166 reads (21%) | catalogued as rs1204792609, COSV56880749; called by muse, mutect2, varscan2
- GLIPR1L1 | c.33G>T p.W11C | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100157236, COSV56880776; called by muse, mutect2, varscan2
- KLC3 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as COSV101229020; called by muse, mutect2, varscan2
- KLHL21 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as COSV100887176; called by muse, mutect2, varscan2
- MKI67 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV64072318; called by muse, mutect2, varscan2
- MORC1 | c.2440G>C p.V814L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV99224839; called by muse, mutect2, varscan2
- MYH1 | c.4764C>G p.D1588E | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1182630992, COSV99874643; called by muse, mutect2
- MYH7 | c.1158C>A p.Y386* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100805593; called by muse, mutect2, varscan2
- PABPC3 | c.1601T>A p.V534E | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV99878919; called by muse, mutect2, varscan2
- PACC1 | c.1042C>A p.H348N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV99800664; called by muse, mutect2, varscan2
- PARVB | c.29G>T p.R10I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV100601205; called by muse, mutect2, varscan2
- PCDHB8 | c.1438G>C p.D480H | Missense Mutation (SNP) | VAF 51/460 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554281219, COSV99175256; called by muse, mutect2, varscan2
- PDE11A | c.1950G>A p.W650* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99610572; called by muse, mutect2, varscan2
- PGM5 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1554678683, COSV101123322; called by muse, mutect2
- RAG2 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100270993, COSV100271167; called by muse, mutect2
- RNF216 | c.851T>C p.V284A (on ENST00000425013 / NM_207116.3; = p.V341A on NM_207111.4) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV101111249; called by muse, mutect2, varscan2
- SLITRK3 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99578225; called by muse, mutect2, varscan2
- SMARCA2 | c.3208C>A p.L1070M | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100570136; called by muse, mutect2, varscan2
- TLN1 | c.5816G>A p.C1939Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.53); catalogued as COSV100147194; called by muse, mutect2
- TMEM123 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV100772216; called by muse, mutect2, varscan2
- ZFP41 | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV100414577; called by muse, mutect2, varscan2
- ZFP69 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV101018065; called by muse, mutect2, varscan2
- DPY19L2 | c.383_384del p.F128* | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- KCTD10 | c.455_456del p.L152Hfs*6 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- ZER1 | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ANKRD17 | c.7764A>T p.G2588= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100428407; called by muse, mutect2, varscan2
- CADPS | c.1401A>G p.T467= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99335433; called by muse, mutect2, varscan2
- CDHR3 | c.1992G>T p.A664= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100487854, COSV58419166; called by muse, mutect2, varscan2
- GALK1 | c.396A>C p.S132= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV99849027; called by muse, mutect2, varscan2
- KLHL42 | c.177G>A p.A59= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV101179681; called by muse, mutect2
- LMF2 | c.1707T>G p.P569= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as COSV99327327; called by muse, mutect2, varscan2
- OBSCN | c.7074C>T p.T2358= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99471210; called by muse, mutect2, varscan2
- OR4C16 | c.771A>C p.T257= | Silent (SNP) | VAF 70/113 reads (62%) | catalogued as rs371509327; called by muse, mutect2, varscan2
- PCDHB4 | c.1875C>A p.T625= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV99521773; called by muse, mutect2, varscan2
- SOX12 | c.804C>T p.S268= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs760848645, COSV100705192; called by muse, mutect2, varscan2
- SSH3 | c.570G>C p.R190= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100354306; called by muse, mutect2, varscan2
- AC244258.1 | n.345A>C | RNA (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- RPL39L | c.*1G>A | 3'UTR (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99961489; called by muse, mutect2, varscan2
